Somatic mutation profile of tumor specimen TCGA-ZB-A966-01A (aliquot TCGA-ZB-A966-01A-11D-A428-09) from TCGA case TCGA-ZB-A966, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 78.4 years (28,621 days).
Specimen TCGA-ZB-A966-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5a7f6432-94c2-4498-bd9e-315363e36e89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZB-A966-10A (Blood Derived Normal), aliquot TCGA-ZB-A966-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5e1dbe36-c1dc-4d42-8618-80b4f480bf03

The open-access MAF lists 740 somatic variants for this specimen: 580 protein-altering or splice-affecting, 140 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 378, Silent 140, Frame Shift Del 137, Frame Shift Ins 29, Nonsense Mutation 19, Intron 9, In Frame Del 7, Splice Region 5, RNA 4, Splice Site 4, 3'UTR 3, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1934del p.G645Vfs*58 | Frame Shift Del (DEL) | VAF 21/57 reads (37%) | hotspot (GDC flag); catalogued as rs750318549; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- FANCI | c.3854G>A p.R1285Q (on ENST00000310775 / NM_001376911.1; = p.R1225Q on NM_018193.3) | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121918163, CM071754; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GALC | c.1591C>T p.R531C | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749893889, CM970566, COSV99730818; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MAGEL2 | c.1996del p.Q666Sfs*36 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | catalogued as rs770374710, CD1510958; ClinVar: pathogenic; called by mutect2, varscan2
- MLH1 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 16/47 reads (34%) | catalogued as rs63751012, CM055990, CM101371, CM1413027, COSV51615011, COSV51624704, COSV99212331; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.687del p.A230Lfs*16 | Frame Shift Del (DEL) | VAF 26/101 reads (26%) | catalogued as rs63749897; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- MYH11 | c.5787-4707del | Intron (DEL) | VAF 14/69 reads (20%) | catalogued as rs747392139, COSV100257523; ClinVar: uncertain significance / benign / likely benign / likely pathogenic; called by mutect2, varscan2
- MYO6 | c.2751del p.K917Nfs*10 | Frame Shift Del (DEL) | VAF 14/46 reads (30%) | catalogued as rs551348450; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- PDZD7 | c.166dup p.R56Pfs*24 | Frame Shift Ins (INS) | VAF 25/92 reads (27%) | catalogued as rs587776894; ClinVar: pathogenic / risk factor; called by mutect2, varscan2
- TP53 | c.817C>T p.R273C | Missense Mutation (SNP) | VAF 5/15 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913343, CM010471, CM010473, CM951233, COSV52662066, COSV52670856, COSV52707054, COSV53164203; ClinVar: not provided / uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.248G>A p.R83H | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.035); catalogued as rs751367482, COSV66057771; called by muse, mutect2, varscan2
- ABCA2 | c.2621C>T p.T874M (on ENST00000614293; = p.T844M on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); catalogued as rs765604778; called by muse, varscan2
- ABCA6 | c.917del p.L306Yfs*7 | Frame Shift Del (DEL) | VAF 24/68 reads (35%) | catalogued as rs750282619, COSV52635694; called by mutect2, varscan2
- ABCG1 | c.1277G>A p.R426H | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772426399; called by muse, mutect2, varscan2
- ABLIM3 | c.1637G>A p.R546Q | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as rs138587496; called by muse, varscan2
- AC004922.1 | c.652C>T p.R218C | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.946); catalogued as rs1209496423, COSV99501349; called by muse, mutect2, varscan2
- ACBD3 | c.530C>T p.A177V | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1311828818; called by muse, mutect2, varscan2
- ADCY5 | c.3421G>A p.D1141N | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.581); catalogued as rs1199215589, COSV59194029; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 16/56 reads (29%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRF4 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1008970738; called by muse, mutect2, varscan2
- ADGRL2 | c.3787A>G p.I1263V (on ENST00000370717 / NM_001366005.1; = p.I1207V on NM_012302.4) | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs769048815; called by muse, mutect2, varscan2
- AFG3L2 | c.2234del p.L745Wfs*96 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs757726488; called by mutect2, pindel, varscan2
- AGAP1 | c.463G>A p.V155I | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.121); catalogued as rs200676786; called by muse, mutect2, varscan2
- AGBL5 | c.1853G>A p.R618Q | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.57); catalogued as rs1468261345; called by mutect2, varscan2
- AGPAT4 | c.907del p.R303Gfs*7 | Frame Shift Del (DEL) | VAF 12/56 reads (21%) | catalogued as rs750826126, COSV57248889; called by mutect2, pindel, varscan2
- AIMP2 | c.608C>T p.T203M | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.809); catalogued as rs766467029; called by muse, mutect2, varscan2
- AKAP6 | c.4283C>T p.S1428L | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs537245618, COSV99798410; called by muse, mutect2, varscan2
- AKAP7 | c.236del p.K79Rfs*21 | Frame Shift Del (DEL) | VAF 20/70 reads (29%) | catalogued as rs763109484, COSV100818792; called by mutect2, varscan2
- ALDH5A1 | c.515G>A p.R172H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs773814880, COSV62373402, COSV62374578; ClinVar: uncertain significance; called by muse, mutect2
- ANK3 | c.4369C>T p.R1457* (on ENST00000280772 / NM_001320874.2; = p.R582* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as COSV104383700; called by muse, varscan2
- ANO1 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1555047278, COSV60281442; called by muse, mutect2, varscan2
- ANOS1 | c.1279C>T p.R427C | Missense Mutation (SNP) | VAF 31/87 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.719); catalogued as rs371623420; called by muse, mutect2, varscan2
- ARGLU1 | c.497G>A p.R166H | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.984); catalogued as rs1402870612, COSV62271387; called by muse, mutect2, varscan2
- ARHGAP31 | c.3407A>G p.E1136G | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.005); catalogued as rs1175867594; called by muse, mutect2, varscan2
- ARHGEF17 | c.1418C>T p.T473M | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); catalogued as rs1047609049, COSV99735760; called by muse, mutect2, varscan2
- ARHGEF26 | c.169G>T p.G57W | Missense Mutation (SNP) | VAF 24/115 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.171); catalogued as rs761099703; called by muse, mutect2, varscan2
- ARSH | c.796dup p.S266Ffs*20 | Frame Shift Ins (INS) | VAF 22/72 reads (31%) | catalogued as rs747035216; called by mutect2, varscan2
- ATP1A2 | c.291del p.F98Sfs*72 | Frame Shift Del (DEL) | VAF 17/70 reads (24%) | catalogued as COSV63403422; called by mutect2, pindel, varscan2
- ATP2B4 | c.2276C>A p.T759N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV100397498; called by muse, mutect2, varscan2
- AVPR1B | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65637806; called by muse, mutect2, varscan2
- AWAT2 | c.648G>A p.G216= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV52144192; called by muse, mutect2, varscan2
- AXL | c.2012G>T p.R671L (on ENST00000301178 / NM_021913.5; = p.R662L on NM_001699.6) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56564998; called by muse, varscan2
- BAHD1 | c.1733C>A p.P578Q | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.351); catalogued as rs756162183, COSV69083622; called by muse, mutect2, varscan2
- BNC2 | c.1553C>T p.A518V | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.378); catalogued as rs1318800426; called by muse, mutect2, varscan2
- BOC | c.1103G>A p.R368H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.633); catalogued as rs1458137582, COSV104383248; called by muse, varscan2
- C1QC | c.235G>A p.G79S | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1224349185; called by muse, mutect2, varscan2
- C1orf127 | c.2359del p.A787Pfs*7 | Frame Shift Del (DEL) | VAF 5/10 reads (50%) | catalogued as rs1283160262; called by mutect2, varscan2
- C7orf50 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs190705576; called by muse, mutect2, varscan2
- CAB39L | c.734T>C p.M245T | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1235025302; called by muse, mutect2, varscan2
- CACNA1G | c.6891del p.P2298Lfs*16 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | catalogued as rs1264658901; called by mutect2, pindel, varscan2
- CACNA2D2 | c.493A>G p.K165E | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.597); catalogued as rs1272154597; called by muse, mutect2, varscan2
- CALM3 | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV52194735; called by muse, mutect2, varscan2
- CAMTA2 | c.2597del p.P866Lfs*9 | Frame Shift Del (DEL) | VAF 12/42 reads (29%) | catalogued as rs745547658; called by mutect2, varscan2
- CARD19 | c.143C>T p.A48V | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.981); catalogued as rs752738422, COSV100968717; called by muse, mutect2, varscan2
- CATSPERG | c.2480C>T p.T827M | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.178); catalogued as rs200588516, COSV53046116; called by muse, mutect2, varscan2
- CCDC114 | c.1355C>T p.P452L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs768434176, COSV59556276, COSV59557080, COSV99043756; called by muse, mutect2, varscan2
- CCDC150 | c.1684G>A p.G562R | Missense Mutation (SNP) | VAF 24/107 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs200176761; called by muse, mutect2, varscan2
- CCDC27 | c.533del p.G178Afs*32 | Frame Shift Del (DEL) | VAF 4/18 reads (22%) | catalogued as COSV53898443; called by pindel, varscan2
- CCDC63 | c.94C>T p.R32W | Missense Mutation (SNP) | VAF 25/63 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs754942747, COSV57526841; called by muse, mutect2, varscan2
- CCNB3 | c.3337C>T p.R1113W | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs781953756, COSV52078579; called by muse, mutect2, varscan2
- CD4 | c.1211dup p.V405Rfs*37 | Frame Shift Ins (INS) | VAF 6/25 reads (24%) | catalogued as rs782711669; called by mutect2, pindel, varscan2
- CDC42BPG | c.2549G>A p.R850H | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.707); catalogued as rs1001290714; called by muse, mutect2, varscan2
- CDKL2 | c.222del p.K74Nfs*5 | Frame Shift Del (DEL) | VAF 16/45 reads (36%) | catalogued as rs753353408; called by mutect2, varscan2
- CELSR1 | c.4406+1G>A p.X1469_splice | Splice Site (SNP) | VAF 21/58 reads (36%) | catalogued as rs1473124282, COSV53088663; called by muse, mutect2, varscan2
- CENPL | c.364dup p.S122Ffs*29 | Frame Shift Ins (INS) | VAF 58/221 reads (26%) | catalogued as rs1359644753; called by mutect2, pindel, varscan2
- CEP170B | c.2656dup p.H886Pfs*47 (on ENST00000453495; = p.H815Pfs*47 on NM_015005.3) | Frame Shift Ins (INS) | VAF 17/49 reads (35%) | catalogued as rs1566868080; called by mutect2, varscan2
- CHRM3 | c.1700del p.K567Rfs*31 | Frame Shift Del (DEL) | VAF 7/35 reads (20%) | catalogued as rs751548647; called by mutect2, varscan2
- CLDN10 | c.178G>A p.V60I | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.74); catalogued as COSV54824266; called by muse, mutect2, varscan2
- CLEC16A | c.1186G>A p.V396I | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.129); catalogued as rs774312800, COSV68499663; called by muse, mutect2, varscan2
- CLIC4 | c.214G>A p.G72R | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as rs1347726916; called by muse, mutect2, varscan2
- CLIP2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs782615936, COSV56281545; called by muse, mutect2
- CLMP | c.937C>T p.R313C | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.719); catalogued as rs142752755; called by muse, mutect2
- CLOCK | c.368del p.L123* | Frame Shift Del (DEL) | VAF 22/65 reads (34%) | catalogued as rs369752219; called by mutect2, varscan2
- CNGA1 | c.1327del p.T443Qfs*8 | Frame Shift Del (DEL) | VAF 5/19 reads (26%) | catalogued as rs772867912; called by mutect2, pindel, varscan2
- CNGB1 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 19/43 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.835); catalogued as rs775102648; called by muse, mutect2, varscan2
- COL17A1 | c.1170del p.E391Kfs*12 | Frame Shift Del (DEL) | VAF 21/71 reads (30%) | catalogued as rs769586532; called by mutect2, pindel, varscan2
- COX18 | c.583del p.A195Qfs*13 | Frame Shift Del (DEL) | VAF 14/76 reads (18%) | catalogued as COSV99886927; called by mutect2, pindel, varscan2
- CPXM1 | c.1402T>C p.Y468H | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1225741742; called by muse, mutect2, varscan2
- CPZ | c.1189del p.Q397Rfs*28 (on ENST00000360986 / NM_001014447.3; = p.Q386Rfs*28 on NM_003652.3) | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as rs1313084590, COSV100248886; called by mutect2, pindel, varscan2
- CRTC1 | c.1713del p.S572Afs*6 | Frame Shift Del (DEL) | VAF 69/115 reads (60%) | catalogued as rs769538822; called by mutect2, varscan2
- CRYBA1 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.973); catalogued as rs769366952; called by muse, mutect2, varscan2
- DCN | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs748901311, COSV99272167; called by muse, mutect2, varscan2
- DDX27 | c.2072del p.K691Rfs*4 | Frame Shift Del (DEL) | VAF 24/72 reads (33%) | catalogued as rs766714372; called by mutect2, varscan2
- DHX58 | c.421G>A p.V141I | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as rs150385537; called by muse, mutect2, varscan2
- DMD | c.414G>T p.K138N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55857945, COSV99922134; called by muse, mutect2, varscan2
- DNAH17 | c.3661G>A p.E1221K | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs753583231, COSV67751712, COSV67754860; called by muse, mutect2, varscan2
- DNAH2 | c.9851C>T p.S3284L | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs140494502; called by muse, mutect2, varscan2
- DNMBP | c.4670C>T p.A1557V | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as COSV100143751; called by muse, mutect2, varscan2
- DOCK2 | c.2527G>A p.V843I | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.427); catalogued as COSV56991359; called by muse, mutect2, varscan2
- DOCK4 | c.3975dup p.F1326Ifs*8 | Frame Shift Ins (INS) | VAF 32/102 reads (31%) | catalogued as rs1302968470; called by mutect2, varscan2
- DPYS | c.1086del p.G363Afs*33 | Frame Shift Del (DEL) | VAF 20/67 reads (30%) | catalogued as COSV60907400; called by mutect2, varscan2
- DYNC1I2 | c.169del p.R57Gfs*13 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | catalogued as rs772082432; called by mutect2, varscan2
- ECHDC2 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs200827816; called by muse, mutect2, varscan2
- EEF1A1 | c.1301C>T p.A434V | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.029); catalogued as COSV58550546; called by muse, mutect2, varscan2
- EFHB | c.2278C>T p.R760W | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs779534510, COSV99858988; called by muse, mutect2, varscan2
- EML1 | c.972del p.F324Lfs*41 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as COSV99214925; called by mutect2, pindel, varscan2
- ENTHD1 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1000774344; called by muse, mutect2, varscan2
- EPHB3 | c.1357C>A p.P453T | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV57804602; called by muse, mutect2, varscan2
- ERLIN2 | c.*6del | Frame Shift Del (DEL) | VAF 11/41 reads (27%) | catalogued as COSV99379658; called by mutect2, pindel, varscan2
- ERN2 | c.1399del p.L467Wfs*48 | Frame Shift Del (DEL) | VAF 5/30 reads (17%) | catalogued as rs763540496, COSV99078581; called by mutect2, pindel
- EXOC2 | c.1753C>T p.R585C | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.505); catalogued as rs752593105, COSV57861866; called by muse, mutect2, varscan2
- FASTKD3 | c.428del p.K143Rfs*36 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as rs773607911, COSV52947201; called by mutect2, pindel, varscan2
- FGF3 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.998); catalogued as rs79472069; called by muse, mutect2, varscan2
- FGF6 | c.306del p.D103Tfs*26 | Frame Shift Del (DEL) | VAF 10/33 reads (30%) | catalogued as COSV57403745, COSV57404438; called by mutect2, pindel, varscan2
- FKBP6 | c.124G>A p.V42I | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs782250810; called by muse, mutect2, varscan2
- FLG | c.12056C>T p.A4019V | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.038); catalogued as rs372573825, COSV64243294; called by muse, mutect2, varscan2
- GDF5 | c.814C>T p.R272W | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as rs1480820638, COSV65499677; called by muse, mutect2, varscan2
- GDPD2 | c.38G>A p.R13H | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as rs757043874; called by muse, mutect2, varscan2
- GLB1L2 | c.839C>T p.T280M | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs147686340; called by muse, mutect2, varscan2
- GPC6 | c.283C>T p.R95C | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs760150200, COSV65500771, COSV65503817; called by muse, mutect2, varscan2
- GPI | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.277); catalogued as rs776925897; called by muse, mutect2, varscan2
- GRIN3A | c.2570C>T p.A857V | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.755); catalogued as COSV62457748; called by muse, mutect2, varscan2
- GRIP1 | c.2393C>T p.T798M (on ENST00000359742 / NM_001379345.1; = p.T746M on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs200363939; called by muse, mutect2, varscan2
- GRWD1 | c.1075G>A p.V359I | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.98); catalogued as rs745784143, COSV53517763; called by muse, mutect2, varscan2
- GTF2F1 | c.365C>T p.T122M | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs754673244, COSV101081235; called by muse, mutect2
- HDX | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV52983175; called by muse, mutect2, varscan2
- HECW1 | c.1574G>A p.R525Q | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV67837732; called by muse, mutect2
- HIVEP2 | c.3082C>T p.R1028* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV50007394; called by muse, mutect2, varscan2
- HMCES | c.292C>T p.R98C | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1415931820, COSV101077289; called by muse, mutect2, varscan2
- HOATZ | c.295C>A p.L99I | Missense Mutation (SNP) | VAF 63/245 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as COSV60440855; called by muse, mutect2, varscan2
- HTR1A | c.281C>T p.A94V | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.994); catalogued as COSV100109343; called by muse, mutect2, varscan2
- HYOU1 | c.2744G>T p.R915L | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.235); catalogued as COSV68215898; called by muse, mutect2, varscan2
- HYPK | c.308G>A p.R103H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1440063953, COSV51039229; called by muse, mutect2, varscan2
- IGHA2 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs113035575; called by muse, mutect2, varscan2
- IL12RB1 | c.1123G>A p.G375S | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.769); catalogued as COSV59096837; called by muse, mutect2
- ING5 | c.164C>T p.T55M | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.713); catalogued as rs1354769907, COSV57978517; called by muse, mutect2
- INTS9 | c.1052_1055del p.K351Rfs*22 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs773661159; called by pindel, varscan2
- IQCB1 | c.1281G>A p.A427= | Splice Region (SNP) | VAF 19/83 reads (23%) | catalogued as rs201319850; called by muse, mutect2, varscan2
- IQSEC3 | c.2240A>G p.E747G (on ENST00000538872 / NM_001170738.2; = p.E444G on NM_015232.1) | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100407444; called by muse, mutect2, varscan2
- IRF5 | c.1190_1192del p.F397del | In Frame Del (DEL) | VAF 6/33 reads (18%) | catalogued as rs778940702; called by pindel, varscan2
- IRS4 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.531); catalogued as COSV100929848; called by muse, mutect2, varscan2
- ITGB3 | c.188G>A p.R63H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370054364; called by muse, mutect2, varscan2
- JAM2 | c.283C>T p.R95W | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.244); catalogued as rs372458284; called by muse, mutect2, varscan2
- JHY | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV99914060; called by muse, mutect2, varscan2
- KCNAB1 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs370498904, COSV101051438; called by muse, mutect2, varscan2
- KCNK3 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs1188597842; called by muse, mutect2, varscan2
- KCNS2 | c.110G>A p.R37H | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1184225176; called by muse, mutect2, varscan2
- KIF4A | c.175A>G p.T59A | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs1483094367, COSV53452685; called by muse, mutect2, varscan2
- KIF9 | c.316del p.A106Qfs*21 | Frame Shift Del (DEL) | VAF 14/31 reads (45%) | catalogued as rs1374368753; called by mutect2, pindel, varscan2
- KLF15 | c.338C>T p.A113V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1310269411; called by muse, mutect2, varscan2
- KLHL12 | c.1699G>A p.E567K | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); catalogued as rs1557983229; called by muse, mutect2, varscan2
- KLHL6 | c.1744G>A p.E582K | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.78); PolyPhen benign (0.041); catalogued as COSV58067835; called by muse, mutect2, varscan2
- KLK1 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56828304; called by muse, mutect2
- KNOP1 | c.467del p.K156Rfs*57 | Frame Shift Del (DEL) | VAF 9/34 reads (26%) | catalogued as rs960845807, COSV54929560; called by mutect2, pindel, varscan2
- KPRP | c.799del p.R267Afs*19 | Frame Shift Del (DEL) | VAF 18/80 reads (23%) | catalogued as COSV100908740; called by mutect2, pindel, varscan2
- KPTN | c.559G>A p.V187M | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.565); catalogued as rs1247339609; called by muse, mutect2, varscan2
- KRT17 | c.1295G>A p.R432H | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as rs754747437; called by muse, mutect2, varscan2
- LENG8 | c.2209C>T p.R737C | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359892473; called by muse, mutect2
- LGI4 | c.496G>A p.V166I | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs778512458; called by muse, mutect2
- LPCAT1 | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1220288606, COSV52039210; called by muse, mutect2, varscan2
- LRCH4 | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs766099566, COSV59642946; called by muse, mutect2, varscan2
- LRRC34 | c.1015G>A p.A339T (on ENST00000446859 / NM_001172779.2; = p.A307T on NM_153353.5) | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs753134335, COSV57187296; called by muse, mutect2, varscan2
- LRRC52 | c.586G>A p.A196T | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs149365089; called by muse, mutect2, varscan2
- LRRIQ1 | c.1103del p.K368Rfs*4 | Frame Shift Del (DEL) | VAF 33/96 reads (34%) | catalogued as rs755230729; called by mutect2, pindel, varscan2
- LUZP1 | c.346C>T p.R116* | Nonsense Mutation (SNP) | VAF 14/50 reads (28%) | catalogued as rs748500182, COSV56504486; called by muse, mutect2, varscan2
- LZTS3 | c.1886G>A p.R629H (on ENST00000329152; = p.R583H on NM_001282533.2) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs769528128, COSV53904306; called by muse, mutect2, varscan2
- MAP3K13 | c.1766G>A p.R589H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs746928773; called by muse, mutect2, varscan2
- MAP3K19 | c.2087G>A p.R696H | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as rs368406495; called by muse, mutect2, varscan2
- MAP7D1 | c.1252_1254del p.K418del | In Frame Del (DEL) | VAF 6/38 reads (16%) | catalogued as rs752518838; called by pindel, varscan2
- MB21D2 | c.1371dup p.L458Tfs*7 | Frame Shift Ins (INS) | VAF 10/24 reads (42%) | catalogued as rs34835215; called by mutect2, varscan2
- MDN1 | c.16054C>T p.R5352* | Nonsense Mutation (SNP) | VAF 12/50 reads (24%) | catalogued as rs1360714310, COSV65516470; called by muse, mutect2, varscan2
- MED14 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.43); PolyPhen benign (0.151); catalogued as rs759092950, COSV61355817; called by muse, mutect2, varscan2
- MEGF6 | c.4318dup p.A1440Gfs*4 | Frame Shift Ins (INS) | VAF 8/36 reads (22%) | catalogued as rs759225724; called by mutect2, varscan2
- MERTK | c.2720C>T p.T907I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs202205484; called by muse, mutect2, varscan2
- METTL17 | c.539G>A p.R180Q | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.176); catalogued as rs188874835; called by muse, mutect2, varscan2
- MLH3 | c.4267C>T p.R1423C (on ENST00000355774 / NM_001040108.2; = p.R1399C on NM_014381.3) | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs1278350332, COSV53152650; called by muse, mutect2, varscan2
- MORC2 | c.2678G>A p.R893H (on ENST00000397641 / NM_001303256.3; = p.R831H on NM_014941.3) | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.247); catalogued as rs202243108; called by muse, mutect2, varscan2
- MORC3 | c.1214G>A p.R405H | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs780018142, COSV68203608; called by muse, mutect2, varscan2
- MPHOSPH8 | c.1265G>A p.R422K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1165112292; called by muse, mutect2, varscan2
- MPST | c.553G>A p.A185T (on ENST00000341116 / NM_001369904.2; = p.A205T on NM_021126.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.24); PolyPhen benign (0.119); catalogued as rs1424555129; called by muse, mutect2, varscan2
- MRGPRF | c.473G>A p.R158H | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs756775637; called by muse, mutect2, varscan2
- MRGPRX3 | c.560del p.L187Yfs*25 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | catalogued as rs1178892676; called by mutect2, pindel, varscan2
- MROH1 | c.2062G>A p.A688T | Missense Mutation (SNP) | VAF 22/58 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.456); catalogued as rs1015855517; called by muse, mutect2, varscan2
- MROH5 | c.92del p.P31Lfs*6 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | catalogued as rs748849454; called by mutect2, pindel, varscan2
- MTOR | c.7412C>T p.T2471M | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as rs1228569453, COSV63879176; called by muse, mutect2, varscan2
- MUS81 | c.1579C>T p.R527C | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as rs1479386637, COSV57259947; called by muse, mutect2, varscan2
- MYH13 | c.2722C>T p.R908W | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751366719, COSV52830773; called by muse, mutect2, varscan2
- MYH14 | c.407C>T p.T136M | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYT1L | c.1711G>A p.G571R | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1330054460; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NAA25 | c.2399G>A p.R800Q | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs747564104; called by muse, mutect2, varscan2
- NACC2 | c.251_253del p.F84del | In Frame Del (DEL) | VAF 9/38 reads (24%) | catalogued as rs1275718153; called by mutect2, pindel, varscan2
- NCR1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs587627160, COSV52555483, COSV99401278; called by muse, mutect2, varscan2
- NIPBL | c.1513del p.R505Efs*35 | Frame Shift Del (DEL) | VAF 20/75 reads (27%) | catalogued as rs34314728; called by mutect2, pindel, varscan2
- NIPSNAP3A | c.164A>T p.N55I | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV66113718; called by muse, mutect2, varscan2
- NKIRAS2 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782402155, COSV56918101; called by muse, mutect2, varscan2
- NLK | c.576del p.F192Lfs*30 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | catalogued as COSV69407880; called by mutect2, pindel, varscan2
- NME9 | c.742G>A p.V248I (on ENST00000333911 / NM_001349024.2; = p.V187I on NM_178130.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.017); catalogued as rs763521362, COSV58616800; called by muse, mutect2, varscan2
- NOD1 | c.400C>T p.R134* | Nonsense Mutation (SNP) | VAF 6/10 reads (60%) | catalogued as rs371807148; called by muse, varscan2
- NOS3 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs755905128; called by muse, mutect2, varscan2
- NR0B1 | c.977G>A p.R326Q | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as rs1260596915; called by muse, mutect2, varscan2
- NRXN2 | c.808del p.A270Pfs*57 | Frame Shift Del (DEL) | VAF 35/116 reads (30%) | catalogued as rs754860965; called by mutect2, varscan2
- NSUN5 | c.852_854del p.E284del | In Frame Del (DEL) | VAF 6/40 reads (15%) | catalogued as rs1316830059; called by pindel, varscan2
- NT5C1B | c.613C>T p.R205C (on ENST00000359846 / NM_001199086.2; = p.R145C on NM_033253.4) | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.792); catalogued as rs764194785, COSV58397080; called by muse, varscan2
- NTNG2 | c.895C>T p.R299C | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.64); catalogued as rs1315897345, COSV100647437; called by muse, mutect2, varscan2
- NUF2 | c.800del p.N267Mfs*44 | Frame Shift Del (DEL) | VAF 68/331 reads (21%) | catalogued as rs1231937327; called by mutect2, pindel, varscan2
- OGDHL | c.2486G>A p.R829H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774307179; called by muse, mutect2, varscan2
- OLFM1 | c.1081G>A p.E361K (on ENST00000371793 / NM_001282611.2; = p.E343K on NM_014279.5) | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1222086077; called by muse, mutect2, varscan2
- OR10G8 | c.421A>G p.T141A | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs200971859; called by muse, mutect2, varscan2
- OR11A1 | c.421C>T p.R141W | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs138146725; called by muse, mutect2, varscan2
- OR3A1 | c.413G>C p.R138P | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.648); catalogued as rs143631940; called by muse, mutect2
- OR4N2 | c.245T>C p.L82S | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758444186; called by muse, mutect2, varscan2
- OR51E1 | c.466del p.A156Lfs*3 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | catalogued as rs1564877761; called by mutect2, pindel, varscan2
- OR51V1 | c.667C>A p.L223M | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.199); catalogued as rs548436244, COSV58315453; called by muse, mutect2, varscan2
- OR52A5 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as rs1447706454; called by muse, mutect2, varscan2
- OR52J3 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs752899018, COSV66747453; called by muse, mutect2, varscan2
- OR6C76 | c.763A>G p.M255V | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.066); catalogued as COSV100094005; called by muse, mutect2, varscan2
- OR8J3 | c.269A>G p.K90R | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.611); catalogued as rs762621665; called by muse, mutect2, varscan2
- ORC3 | c.610del p.R204Gfs*16 | Frame Shift Del (DEL) | VAF 38/135 reads (28%) | catalogued as rs1336736903; called by mutect2, pindel, varscan2
- OTOF | c.2360G>A p.R787H (on ENST00000272371 / NM_194248.3; = p.R40H on NM_004802.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.138); catalogued as rs867139017, COSV99717095; called by muse, mutect2, varscan2
- P3H2 | c.1918C>T p.R640C | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758007118, COSV60018176; called by muse, mutect2, varscan2
- PAQR8 | c.680C>A p.P227H | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62443619; called by muse, mutect2, varscan2
- PARP4 | c.4525G>A p.E1509K | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as rs748983082; called by muse, mutect2, varscan2
- PCBP2 | c.914G>A p.R305H (on ENST00000439930 / NM_001128911.2; = p.R306H on NM_005016.6) | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.047); catalogued as COSV63727838; called by muse, mutect2
- PCDHB6 | c.1217C>T p.A406V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.26); catalogued as COSV50700643; called by muse, mutect2, varscan2
- PCDHGA1 | c.1883C>T p.T628M | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs747200046, COSV100966071, COSV65296718; called by muse, mutect2, varscan2
- PCK2 | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs551184706, COSV53748018; called by mutect2, varscan2
- PCNX2 | c.3442C>T p.R1148C | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768375165, COSV50865368; called by muse, varscan2
- PCP2 | c.226C>T p.R76C | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as rs754749924; called by muse, mutect2, varscan2
- PDE7B | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57510189; called by muse, mutect2, varscan2
- PDE9A | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.029); catalogued as rs867454705, COSV52322790; called by muse, mutect2, varscan2
- PELP1 | c.2274dup p.R759Efs*11 | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | catalogued as rs770510786; called by mutect2, pindel, varscan2
- PFKM | c.629G>A p.R210H | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs888929546, COSV56659333; called by muse, mutect2, varscan2
- PHF10 | c.338G>A p.R113Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); catalogued as rs761873979; called by muse, mutect2, varscan2
- PIAS3 | c.1016G>A p.R339H | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.046); catalogued as rs781910614; called by muse, mutect2, varscan2
- PLA2G4C | c.1243G>A p.G415R | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs1314178829; called by muse, mutect2, varscan2
- PLEKHA4 | c.115G>A p.A39T | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as rs760684162, COSV54363258; called by muse, mutect2, varscan2
- PLEKHG4B | c.2330del p.P777Rfs*30 (on ENST00000283426; = p.P1133Rfs*30 on NM_052909.5) | Frame Shift Del (DEL) | VAF 11/47 reads (23%) | catalogued as rs746346365, COSV52056100; called by mutect2, pindel, varscan2
- PLK2 | c.1004del p.L335Cfs*68 | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs772701630; called by mutect2, varscan2
- PLXNA2 | c.3961G>A p.A1321T | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.483); catalogued as rs770107131; called by muse, mutect2, varscan2
- PLXNA2 | c.3344G>A p.R1115H | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as rs749983857; called by muse, mutect2, varscan2
- PLXNB1 | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 12/27 reads (44%) | catalogued as rs764417958; called by muse, mutect2, varscan2
- POLR1A | c.340C>T p.R114W | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs765165345; called by muse, mutect2, varscan2
- PPP1R10 | c.977C>T p.T326M | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.143); catalogued as rs569378424; called by muse, mutect2, varscan2
- PPP1R10 | c.930del p.V311Yfs*79 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs746108087; called by mutect2, varscan2
- PPP2R2A | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 10/60 reads (17%) | catalogued as rs1218488964, COSV60095205; called by muse, varscan2
- PPP2R2A | c.1166G>A p.R389H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs369862992, COSV60096160; called by muse, varscan2
- PRAF2 | c.31G>A p.A11T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.56); PolyPhen benign (0.133); catalogued as COSV100540428; called by muse, mutect2
- PRG4 | c.2134A>T p.T712S | Missense Mutation (SNP) | VAF 35/109 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as rs1473962578; called by muse, mutect2, varscan2
- PRKDC | c.3407G>A p.R1136H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.063); catalogued as rs781401034, COSV58044763; called by muse, mutect2, varscan2
- PRKDC | c.496del p.I166Yfs*6 | Frame Shift Del (DEL) | VAF 41/141 reads (29%) | catalogued as rs537061158; called by mutect2, varscan2
- PRKRA | c.784G>T p.D262Y | Missense Mutation (SNP) | VAF 22/62 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as COSV57870023; called by muse, mutect2, varscan2
- PRSS1 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs144403091, CM011004, COSV61192213; ClinVar: uncertain significance; called by muse, varscan2
- PTPRU | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs759619380, COSV60529211; called by muse, mutect2, varscan2
- PXYLP1 | c.1259G>A p.R420Q | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs150898568; called by muse, mutect2, varscan2
- RAB35 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV57567484; called by muse, mutect2, varscan2
- RAD51C | c.47G>A p.S16N | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.398); catalogued as rs1555591843, COSV53624714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RADIL | c.2599C>T p.R867C | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs555892479; called by muse, varscan2
- RADIL | c.1670C>T p.A557V | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.225); catalogued as rs369367147; called by muse, mutect2, varscan2
- RBBP8 | c.2642G>A p.R881H | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs766770356, COSV59091948; called by muse, mutect2, varscan2
- REEP5 | c.14T>C p.M5T | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs780984444; called by muse, mutect2, varscan2
- RELN | c.7954G>A p.D2652N | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.384); catalogued as rs1562865566, COSV59024192; called by muse, mutect2, varscan2
- REXO1 | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs767880392; called by muse, mutect2, varscan2
- RGL1 | c.1034del p.K345Rfs*12 (on ENST00000360851 / NM_001297672.2; = p.K380Rfs*12 on NM_015149.5 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 12/73 reads (16%) | catalogued as rs1290470008; called by mutect2, pindel, varscan2
- RGL3 | c.1786G>A p.A596T | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs774088081; called by muse, mutect2, varscan2
- RGS12 | c.1375G>A p.G459S | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs1427715196, COSV60903174; called by muse, mutect2, varscan2
- RIPPLY3 | c.514del p.E172Rfs*50 | Frame Shift Del (DEL) | VAF 5/20 reads (25%) | catalogued as rs1227193558; called by pindel, varscan2
- RNF128 | c.31del p.W11Gfs*4 | Frame Shift Del (DEL) | VAF 18/64 reads (28%) | catalogued as rs757038390; called by mutect2, varscan2
- ROBO1 | c.2265del p.F755Lfs*28 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as rs1192824348; called by mutect2, pindel, varscan2
- RPN1 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.607); catalogued as rs199783080; called by muse, mutect2, varscan2
- RRP1B | c.543del p.K182Rfs*4 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | catalogued as rs1568956937; called by mutect2, pindel, varscan2
- SAFB | c.2348G>A p.R783H | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs368894379; called by muse, mutect2, varscan2
- SALL3 | c.3166G>A p.A1056T | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs139036373, COSV73305929; called by muse, mutect2, varscan2
- SCO1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.861); catalogued as rs145764824; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SDHB | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763008243; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 18/59 reads (31%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA4D | c.1957G>A p.V653I | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs753165801, COSV59393287; called by muse, mutect2, varscan2
- SEMA5B | c.1949A>T p.D650V | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.028); catalogued as COSV52097571; called by muse, mutect2
- SEPTIN3 | c.551+1G>A p.X184_splice | Splice Site (SNP) | VAF 6/42 reads (14%) | catalogued as rs574717482; called by muse, mutect2, varscan2
- SHC1 | c.1087del p.V363Wfs*2 (on ENST00000368445 / NM_183001.5; = p.V253Wfs*2 on NM_003029.5) | Frame Shift Del (DEL) | VAF 20/60 reads (33%) | catalogued as rs746556543; called by mutect2, varscan2
- SIM1 | c.559G>A p.G187S | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1317491192; called by muse, mutect2, varscan2
- SIN3A | c.377C>T p.A126V | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64582462; called by muse, mutect2, varscan2
- SLC25A17 | c.301A>G p.T101A | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs113893475; called by muse, mutect2, varscan2
- SLC34A2 | c.1186G>A p.A396T | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs560657112, COSV101158196, COSV65940727; called by muse, mutect2, varscan2
- SLC35E4 | c.292del p.A98Hfs*31 | Frame Shift Del (DEL) | VAF 7/24 reads (29%) | catalogued as rs1470004154, COSV55898986; called by mutect2, pindel, varscan2
- SLC45A1 | c.541G>A p.A181T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.687); catalogued as rs868504736, COSV57093006; called by muse, varscan2
- SLC47A2 | c.1681G>A p.A561T | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.38); PolyPhen benign (0.001); catalogued as rs113234335, COSV51565603; called by muse, mutect2, varscan2
- SLC7A2 | c.504del p.F168Lfs*9 (on ENST00000494857 / NM_001370338.1; = p.F208Lfs*9 on NM_003046.6) | Frame Shift Del (DEL) | VAF 17/91 reads (19%) | catalogued as rs780138939; called by mutect2, pindel, varscan2
- SLC8A2 | c.352G>A p.V118M | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as rs1180959523; called by muse, mutect2
- SLF2 | c.2360del p.L787* | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | catalogued as rs1007972651, COSV53275602; called by mutect2, pindel, varscan2
- SLITRK6 | c.1647del p.H551Ifs*7 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | catalogued as rs755387608; called by mutect2, pindel, varscan2
- SND1 | c.2395G>A p.A799T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1490621481, COSV61241701; called by muse, mutect2, varscan2
- SNX1 | c.1202G>A p.R401H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs1426456011; called by muse, mutect2, varscan2
- SON | c.4595T>C p.I1532T | Missense Mutation (SNP) | VAF 16/47 reads (34%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0); catalogued as rs1448713802; called by muse, mutect2, varscan2
- SORBS2 | c.3130del p.E1044Nfs*65 (on ENST00000284776 / NM_021069.5; = p.E610Nfs*65 on NM_003603.6) | Frame Shift Del (DEL) | VAF 29/93 reads (31%) | catalogued as rs772549791, COSV52996321; called by mutect2, pindel, varscan2
- SPAG1 | c.1579C>T p.R527W | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777137396, COSV52559488; called by muse, mutect2, varscan2
- STX6 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 25/94 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs776504795, COSV51111185; called by muse, mutect2, varscan2
- SUPT7L | c.761_762del p.S254* | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs1442402388; called by pindel, varscan2
- TACR3 | c.1249G>A p.D417N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.06); PolyPhen benign (0.001); catalogued as rs778964585, COSV59198545; called by muse, mutect2, varscan2
- TARBP1 | c.3396G>A p.M1132I | Missense Mutation (SNP) | VAF 33/133 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs779595383; called by muse, mutect2, varscan2
- TAS2R14 | c.241dup p.M81Nfs*7 | Frame Shift Ins (INS) | VAF 23/81 reads (28%) | catalogued as rs778784911; called by mutect2, pindel, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 8/40 reads (20%) | catalogued as rs758822980; called by mutect2, varscan2
- TCF7L1 | c.987C>T p.S329= | Splice Region (SNP) | VAF 13/28 reads (46%) | catalogued as rs1193496557; called by muse, mutect2, varscan2
- TCTN2 | c.1700G>A p.R567H | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.081); catalogued as rs780065531, COSV100315316; called by muse, mutect2, varscan2
- TENM4 | c.5534G>A p.R1845H | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.991); catalogued as rs760270892, COSV53637431; called by muse, mutect2, varscan2
- TET3 | c.1606C>T p.R536C | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs780444047; called by muse, mutect2, varscan2
- THBS3 | c.25del p.A9Pfs*19 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs751069667; called by mutect2, pindel
- TIMP3 | c.211C>T p.R71* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as rs778568696, COSV56663693; called by muse, mutect2, varscan2
- TKTL2 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs779776530; called by muse, mutect2, varscan2
- TLN1 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.107); catalogued as rs767796509; called by muse, mutect2, varscan2
- TLR3 | c.2653C>T p.R885W | Missense Mutation (SNP) | VAF 42/136 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774708574; called by muse, mutect2, varscan2
- TMPRSS9 | c.2218G>A p.V740M (on ENST00000648592; = p.V706M on NM_182973.2) | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs769180283; called by muse, mutect2, varscan2
- TPPP | c.575G>A p.R192H | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs745415593, COSV62191766; called by muse, mutect2, varscan2
- TRPC7 | c.724G>A p.A242T | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100725655, COSV61452956; called by muse, varscan2
- TRRAP | c.2165C>G p.S722C | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV62839126, COSV62849075; called by muse, mutect2, varscan2
- TTC6 | c.652A>G p.M218V (on ENST00000267368; = p.M1584V on NM_001310135.3) | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs370029146; called by muse, mutect2, varscan2
- TUBG2 | c.434C>T p.T145M | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756925189, COSV52218186; called by muse, mutect2, varscan2
- TUBGCP3 | c.2704C>T p.R902W | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.359); catalogued as rs138098573; called by muse, mutect2, varscan2
- UBB | c.570dup p.D191Rfs*20 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | catalogued as rs750712511; called by mutect2, varscan2
- UGT2A3 | c.1532dup p.L511Ffs*8 | Frame Shift Ins (INS) | VAF 25/72 reads (35%) | catalogued as rs765679748; called by mutect2, pindel, varscan2
- UGT2B10 | c.964G>A p.V322I | Missense Mutation (SNP) | VAF 53/193 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs369643682; called by muse, mutect2, varscan2
- UNC50 | c.533del p.F178Sfs*7 | Frame Shift Del (DEL) | VAF 19/75 reads (25%) | catalogued as rs752307344; called by mutect2, pindel, varscan2
- USP29 | c.979G>A p.A327T | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.871); catalogued as rs1487892576; called by muse, mutect2
- UTP23 | c.265C>T p.R89* | Nonsense Mutation (SNP) | VAF 16/66 reads (24%) | catalogued as rs754570586; called by muse, mutect2, varscan2
- UTP25 | c.2063A>G p.Y688C | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754744575; called by muse, mutect2, varscan2
- VCP | c.1847del p.N616Mfs*63 | Frame Shift Del (DEL) | VAF 9/30 reads (30%) | catalogued as rs751290466; called by mutect2, varscan2
- VPS26C | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs767397154; called by muse, mutect2, varscan2
- VWA8 | c.483+1G>A p.X161_splice | Splice Site (SNP) | VAF 10/22 reads (45%) | catalogued as rs779442883, COSV55700175; called by muse, mutect2, varscan2
- WASF3 | c.920dup p.P308Afs*29 | Frame Shift Ins (INS) | VAF 16/26 reads (62%) | catalogued as rs756173793; called by mutect2, varscan2
- WDR1 | c.703G>A p.G235S (on ENST00000382452; = p.G95S on NM_005112.5) | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1344082220; called by muse, mutect2, varscan2
- WDR3 | c.790C>T p.R264* | Nonsense Mutation (SNP) | VAF 9/40 reads (23%) | catalogued as rs781395374; called by muse, mutect2, varscan2
- WDR33 | c.3343C>T p.R1115C | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1376491065; called by muse, mutect2, varscan2
- WDR41 | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT tolerated (0.2); PolyPhen benign (0.044); catalogued as rs778375538; called by muse, mutect2, varscan2
- WNT16 | c.500del p.G167Afs*17 (on ENST00000222462 / NM_057168.2; = p.G157Afs*17 on NM_016087.2) | Frame Shift Del (DEL) | VAF 7/28 reads (25%) | catalogued as rs771899177; called by mutect2, pindel, varscan2
- WSB2 | c.558C>T p.H186= | Splice Region (SNP) | VAF 23/64 reads (36%) | catalogued as rs751709403; called by muse, mutect2, varscan2
- XIRP2 | c.1537del p.D513Mfs*5 (on ENST00000628543; = p.D688Mfs*5 on NM_152381.6) | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs745648385; called by mutect2, pindel, varscan2
- XKR6 | c.1168G>A p.V390M | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as rs377188885; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 24/76 reads (32%) | catalogued as rs762052135; called by mutect2, varscan2
- XYLT2 | c.1584del p.G529Afs*78 | Frame Shift Del (DEL) | VAF 6/21 reads (29%) | catalogued as rs779864368; called by mutect2, pindel, varscan2
- ZBTB9 | c.1256G>A p.R419H | Missense Mutation (SNP) | VAF 13/20 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as rs760400106; called by muse, mutect2, varscan2
- ZC3H13 | c.1895G>A p.R632H | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs763604474, COSV54449272, COSV99667632; called by muse, mutect2, varscan2
- ZDHHC16 | c.916_918del p.K306del | In Frame Del (DEL) | VAF 8/26 reads (31%) | catalogued as rs756458996; called by pindel, varscan2
- ZFHX3 | c.7928G>A p.R2643H | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs777599986, COSV51713726; called by muse, mutect2, varscan2
- ZFYVE9 | c.3284G>A p.R1095Q | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs991780823; called by muse, mutect2, varscan2
- ZKSCAN4 | c.1624del p.T542Lfs*27 | Frame Shift Del (DEL) | VAF 10/36 reads (28%) | catalogued as rs757603403; called by mutect2, pindel, varscan2
- ZMIZ2 | c.2340del p.I781Sfs*12 | Frame Shift Del (DEL) | VAF 9/40 reads (23%) | catalogued as rs1279929143; called by mutect2, varscan2
- ZNF343 | c.1246C>T p.R416* | Nonsense Mutation (SNP) | VAF 9/56 reads (16%) | catalogued as rs936793364; called by muse, mutect2, varscan2
- ZNF394 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.954); catalogued as rs1356048984, COSV61793842; called by muse, mutect2, varscan2
- ZNF419 | c.1001A>G p.Q334R | Missense Mutation (SNP) | VAF 24/79 reads (30%) | SIFT tolerated (0.72); PolyPhen benign (0.237); catalogued as rs780315427; called by muse, mutect2, varscan2
- ZNF492 | c.182del p.N61Ifs*6 | Frame Shift Del (DEL) | VAF 22/67 reads (33%) | catalogued as rs754633801; called by mutect2, varscan2
- ZNF536 | c.2521G>A p.A841T | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs200595340, COSV100834809, COSV62823716; called by muse, mutect2, varscan2
- ZNF540 | c.843del p.F281Lfs*4 | Frame Shift Del (DEL) | VAF 13/67 reads (19%) | catalogued as rs757107073, COSV57110076; called by mutect2, pindel, varscan2
- ZNF711 | c.2079del p.K693Nfs*3 | Frame Shift Del (DEL) | VAF 22/71 reads (31%) | catalogued as rs1264060719; called by mutect2, pindel, varscan2
- ABCB4 | c.2134G>A p.V712I | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ABCC2 | c.3868C>T p.P1290S | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ABCC9 | c.3252dup p.D1085* | Frame Shift Ins (INS) | VAF 18/86 reads (21%) | called by mutect2, pindel, varscan2
- ACBD5 | c.222C>A p.F74L (on ENST00000375888 / NM_001352568.1; = p.F76L on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- ADAMTS13 | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2
- ADGRV1 | c.4087C>T p.P1363S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADGRV1 | c.11438C>T p.A3813V | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- AFMID | c.867G>T p.K289N | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ALPL | c.1558del p.L520* | Frame Shift Del (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- ANKRD12 | c.3512dup p.N1171Kfs*14 | Frame Shift Ins (INS) | VAF 12/56 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD34A | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ANO5 | c.2534del p.L845* | Frame Shift Del (DEL) | VAF 18/49 reads (37%) | called by mutect2, pindel, varscan2
- ARHGAP5 | c.2828dup p.N943Kfs*10 | Frame Shift Ins (INS) | VAF 22/68 reads (32%) | called by mutect2, varscan2
- ARHGEF5 | c.727dup p.E243Gfs*24 | Frame Shift Ins (INS) | VAF 7/64 reads (11%) | called by mutect2, varscan2
- ARID2 | c.1763G>A p.S588N | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.71); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID4B | c.2815del p.T939Rfs*2 | Frame Shift Del (DEL) | VAF 10/59 reads (17%) | called by mutect2, pindel, varscan2
- ASH1L | c.1553A>G p.K518R | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.584); called by muse, mutect2, varscan2
- BAZ1A | c.219del p.A74Qfs*12 | Frame Shift Del (DEL) | VAF 16/72 reads (22%) | called by mutect2, varscan2
- BCL9L | c.4388dup p.P1464Afs*53 | Frame Shift Ins (INS) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- BDP1 | c.2974del p.I992Yfs*14 | Frame Shift Del (DEL) | VAF 15/46 reads (33%) | called by mutect2, pindel, varscan2
- BRCA2 | c.9352A>G p.M3118V | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BRD1 | c.1822G>T p.D608Y | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C2orf73 | c.622del p.T208Qfs*11 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | called by mutect2, pindel, varscan2
- CACNA1S | c.4488G>T p.K1496N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.73); called by muse, mutect2
- CAMK2N2 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- CBLC | c.658C>T p.P220S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CC2D1B | c.66G>T p.K22N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- CCDC148 | c.1260del p.K420Nfs*15 | Frame Shift Del (DEL) | VAF 27/89 reads (30%) | called by mutect2, pindel, varscan2
- CCDC172 | c.113T>A p.I38N | Missense Mutation (SNP) | VAF 29/94 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- CCT5 | c.962C>T p.A321V | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDC27 | c.532A>G p.N178D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CDR1 | c.744G>C p.K248N | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- CENPC | c.1428del p.K476Nfs*38 | Frame Shift Del (DEL) | VAF 16/62 reads (26%) | called by mutect2, pindel, varscan2
- CENPH | c.344del p.N115Tfs*16 | Frame Shift Del (DEL) | VAF 18/55 reads (33%) | called by mutect2, varscan2
- CEPT1 | c.553del p.C185Vfs*26 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- CGNL1 | c.2512A>C p.S838R | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CHEK1 | c.215G>T p.G72V | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CILK1 | c.1819A>G p.T607A (on ENST00000350082 / NM_001375397.1; = p.T600A on NM_014920.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/23 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CLASRP | c.284del p.P95Lfs*81 | Frame Shift Del (DEL) | VAF 11/38 reads (29%) | called by mutect2, pindel, varscan2
- CLCNKA | c.1211T>G p.F404C | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- CLSTN2 | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- CMTM5 | c.154T>G p.F52V | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); called by muse, mutect2
- CNOT1 | c.3781G>A p.A1261T | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- COL17A1 | c.2426T>C p.V809A | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- COL6A5 | c.6801T>A p.N2267K (on ENST00000312481; = p.N2263K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.084); called by muse, mutect2, varscan2
- CTR9 | c.1959A>G p.I653M | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- CTSL | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.684); called by muse, mutect2, varscan2
- CUL4A | c.656G>A p.G219D (on ENST00000375440 / NM_001008895.4; = p.G119D on NM_003589.3) | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CYLD | c.2165del p.N722Mfs*13 | Frame Shift Del (DEL) | VAF 24/73 reads (33%) | called by mutect2, pindel, varscan2
- DCHS1 | c.2363C>A p.P788H | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- DHDDS | c.224T>A p.V75D | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DHX37 | c.584C>T p.T195I | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DNA2 | c.2614T>A p.F872I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAH1 | c.8837del p.P2946Rfs*3 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, pindel, varscan2
- DNAJC7 | c.448G>T p.E150* | Nonsense Mutation (SNP) | VAF 15/52 reads (29%) | called by muse, mutect2, varscan2
- DOCK5 | c.4713del p.F1571Lfs*19 | Frame Shift Del (DEL) | VAF 11/37 reads (30%) | called by mutect2, pindel, varscan2
- DPF1 | c.460del p.E154Rfs*6 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by mutect2, pindel, varscan2
- DST | c.6173A>G p.K2058R | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- DTL | c.1528T>C p.S510P | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.543); called by muse, mutect2
- EEF1A1 | c.992del p.N331Mfs*14 | Frame Shift Del (DEL) | VAF 17/60 reads (28%) | called by mutect2, pindel, varscan2
- EIF4G3 | c.247del p.Q83Nfs*43 | Frame Shift Del (DEL) | VAF 32/129 reads (25%) | called by mutect2, pindel, varscan2
- EIF5B | c.2843T>G p.L948R | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- ELAC1 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELMO1 | c.1553G>A p.R518H | Missense Mutation (SNP) | VAF 18/70 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- EMILIN1 | c.1628A>G p.Q543R | Missense Mutation (SNP) | VAF 16/71 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EP300 | c.4030G>A p.V1344M | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EP400 | c.226C>A p.L76M | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPN2 | c.1183del p.V395Cfs*56 | Frame Shift Del (DEL) | VAF 18/56 reads (32%) | called by mutect2, pindel, varscan2
- EPN3 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2, varscan2
- ERBB2 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- ERICH6 | c.1756C>T p.L586F | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.04); called by muse, mutect2
- EXOC6 | c.76A>T p.T26S | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT tolerated (0.95); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- FAM83A | c.965G>A p.S322N | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- FAM98A | c.1093G>T p.G365C | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.003); called by mutect2, varscan2
- FAT4 | c.9417dup p.A3140Cfs*16 | Frame Shift Ins (INS) | VAF 13/45 reads (29%) | called by mutect2, pindel, varscan2
- FBXO43 | c.304A>C p.T102P | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- FGF13 | c.68del p.P23Lfs*19 | Frame Shift Del (DEL) | VAF 8/31 reads (26%) | called by mutect2, pindel, varscan2
- FLG | c.1445A>G p.H482R | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- FLI1 | c.21G>T p.E7D | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- FLT4 | c.990T>A p.N330K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FMN1 | c.2103G>A p.W701* (on ENST00000616417 / NM_001277313.2; = p.W478* on NM_001103184.4) | Nonsense Mutation (SNP) | VAF 26/66 reads (39%) | called by muse, mutect2, varscan2
- FREM2 | c.8858T>C p.V2953A | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- FRS3 | c.740C>T p.T247I | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- FZR1 | c.1124del p.G375Afs*14 | Frame Shift Del (DEL) | VAF 15/29 reads (52%) | called by mutect2, pindel, varscan2
- GALNT16 | c.1157G>A p.R386Q | Missense Mutation (SNP) | VAF 5/25 reads (20%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.901); called by muse, mutect2, varscan2
- GGA1 | c.1141G>T p.G381* | Nonsense Mutation (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- GIGYF1 | c.1235C>T p.S412F | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- GLRX2 | c.290T>C p.V97A (on ENST00000367439 / NM_197962.3; = p.V98A on NM_016066.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- GPATCH8 | c.564dup p.Q189Tfs*10 | Frame Shift Ins (INS) | VAF 18/72 reads (25%) | called by mutect2, pindel, varscan2
- GPR83 | c.103G>A p.V35M | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.042); called by muse, mutect2
- GRIPAP1 | c.1198C>T p.R400* | Nonsense Mutation (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- GTF2B | c.922A>G p.T308A | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- HEATR1 | c.2708_2710del p.S903_Q904delins* | Nonsense Mutation (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- HEATR5B | c.2594del p.N865Tfs*36 | Frame Shift Del (DEL) | VAF 16/60 reads (27%) | called by mutect2, pindel, varscan2
- HERC1 | c.7150C>T p.R2384* | Nonsense Mutation (SNP) | VAF 10/48 reads (21%) | called by muse, mutect2, varscan2
- HERC2 | c.8222A>T p.H2741L | Missense Mutation (SNP) | VAF 58/239 reads (24%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIVEP1 | c.2155C>T p.P719S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- HMCN1 | c.13738A>G p.N4580D | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- HNRNPH2 | c.1142del p.L381* | Frame Shift Del (DEL) | VAF 8/29 reads (28%) | called by mutect2, pindel, varscan2
- HOXA10 | c.431del p.P144Rfs*113 | Frame Shift Del (DEL) | VAF 6/20 reads (30%) | called by mutect2, varscan2
- HOXB5 | c.379A>G p.S127G | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- HP1BP3 | c.163del p.S55Afs*15 | Frame Shift Del (DEL) | VAF 30/124 reads (24%) | called by mutect2, pindel, varscan2
- HTR5A | c.620G>A p.G207D | Missense Mutation (SNP) | VAF 9/24 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- HUWE1 | c.5330C>A p.A1777D | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- IL17RA | c.1387del p.A463Rfs*21 | Frame Shift Del (DEL) | VAF 10/30 reads (33%) | called by mutect2, pindel, varscan2
- IL18 | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 48/178 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.464); called by muse, mutect2, varscan2
- INTS3 | c.3027_3029del p.E1010del | In Frame Del (DEL) | VAF 4/21 reads (19%) | called by pindel, varscan2
- INTS6 | c.581_582del p.S194Cfs*7 | Frame Shift Del (DEL) | VAF 16/64 reads (25%) | called by pindel, varscan2
- JRK | c.896A>T p.D299V | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KAT14 | c.306dup p.R103* | Frame Shift Ins (INS) | VAF 16/44 reads (36%) | called by mutect2, varscan2
- KCND2 | c.1277A>G p.K426R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- KHDC1 | c.346_347del p.Y116Pfs*5 (on ENST00000370384 / NM_001251874.2; = p.Y43Pfs*5 on NM_030568.5) | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- KIAA1210 | c.4877C>T p.P1626L | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- KIF26B | c.3414dup p.S1139Ifs*16 | Frame Shift Ins (INS) | VAF 14/56 reads (25%) | called by mutect2, pindel, varscan2
- KIR3DL2 | c.1360del p.V454Ffs*24 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | called by mutect2, pindel, varscan2
- KLK6 | c.181G>A p.A61T | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- L3MBTL3 | c.1885A>G p.R629G | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.22); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LMBRD2 | c.1028del p.N343Mfs*56 | Frame Shift Del (DEL) | VAF 22/93 reads (24%) | called by mutect2, pindel, varscan2
- LTBP2 | c.4767del p.V1590Sfs*151 | Frame Shift Del (DEL) | VAF 10/39 reads (26%) | called by mutect2, pindel, varscan2
- MCM3AP | c.1763G>A p.C588Y | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.51); called by muse, mutect2, varscan2
- MLLT1 | c.251C>A p.P84H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- MMP19 | c.1442del p.P481Hfs*13 | Frame Shift Del (DEL) | VAF 9/42 reads (21%) | called by mutect2, pindel, varscan2
- MPP1 | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MSH3 | c.2941A>G p.T981A | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MUL1 | c.577del p.A193Pfs*29 | Frame Shift Del (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- MYO10 | c.5996T>A p.I1999N | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NAPG | c.140del p.N47Mfs*13 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- NEO1 | c.1130del p.N377Mfs*14 | Frame Shift Del (DEL) | VAF 15/72 reads (21%) | called by mutect2, pindel, varscan2
- NLRP7 | c.2414del p.G805Vfs*9 (on ENST00000340844 / NM_206828.3; = p.G777Vfs*9 on NM_139176.3) | Frame Shift Del (DEL) | VAF 18/41 reads (44%) | called by mutect2, pindel, varscan2
- NOL11 | c.1750del p.R584Efs*22 | Frame Shift Del (DEL) | VAF 20/63 reads (32%) | called by mutect2, pindel, varscan2
- NOMO3 | c.427G>T p.G143C | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by mutect2, varscan2
- NOP2 | c.1358del p.G453Afs*23 (on ENST00000322166 / NM_001258308.2; = p.G449Afs*23 on NM_006170.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 6/24 reads (25%) | called by mutect2, pindel, varscan2
- NUP43 | c.406G>T p.G136C | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- NXF1 | c.1453G>A p.A485T | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- OFD1 | c.2422del p.S808Vfs*9 | Frame Shift Del (DEL) | VAF 47/184 reads (26%) | called by mutect2, pindel, varscan2
- OR1E1 | c.136A>G p.I46V | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.011); called by muse, mutect2
- OR2K2 | c.892dup p.I298Nfs*? (on ENST00000374428; = p.I269Nfs*? on NM_205859.2) | Frame Shift Ins (INS) | VAF 25/87 reads (29%) | called by mutect2, pindel, varscan2
- PABPN1L | c.745C>A p.P249T | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated (0.39); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- PBRM1 | c.2727del p.K909Nfs*6 | Frame Shift Del (DEL) | VAF 21/55 reads (38%) | called by mutect2, pindel, varscan2
- PCLO | c.8378A>C p.E2793A | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- PCOLCE | c.1157G>A p.C386Y | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDS5A | c.2225G>A p.C742Y | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDZD8 | c.888del p.P297Hfs*32 | Frame Shift Del (DEL) | VAF 27/104 reads (26%) | called by mutect2, pindel, varscan2
- PGC | c.128T>C p.L43P | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PHF3 | c.1631C>T p.P544L | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- PHIP | c.284C>A p.P95H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- PKD1 | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- PLAC9 | c.113C>A p.A38E | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.068); called by muse, mutect2
- PLAUR | c.403C>A p.L135M | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- PLEKHG2 | c.2024C>A p.P675H | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.62); called by muse, mutect2, varscan2
- PLEKHG5 | c.248_249del p.V83Gfs*25 (on ENST00000400915 / NM_001042663.3; = p.V46Gfs*25 on NM_020631.6) | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by pindel, varscan2
- PLEKHG7 | c.71T>G p.L24R | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.102); called by muse, varscan2
- PLXNA1 | c.5239del p.L1747Cfs*5 | Frame Shift Del (DEL) | VAF 9/21 reads (43%) | called by mutect2, varscan2
- PODXL | c.568C>T p.R190* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | called by muse, mutect2
- POLQ | c.3184G>A p.A1062T | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- POU2F3 | c.706A>G p.N236D | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PPM1B | c.39_40del p.H13Qfs*47 | Frame Shift Del (DEL) | VAF 20/72 reads (28%) | called by mutect2, pindel, varscan2
- PPP1R10 | c.2278G>T p.G760C | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- PRDM4 | c.548G>A p.G183D | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- PRICKLE4 | c.121-2A>T p.X41_splice (on ENST00000359201; = p.X81_splice on NM_013397.6) | Splice Site (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- PRRC2B | c.4867C>A p.L1623M | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- PSD3 | c.2865del p.D956Tfs*14 (on ENST00000440756; = p.D955Tfs*14 on NM_015310.4) | Frame Shift Del (DEL) | VAF 12/45 reads (27%) | called by mutect2, pindel, varscan2
- PTH2R | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- PTPRH | c.2587C>A p.L863M | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PVR | c.328A>G p.M110V | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, varscan2
- RAD54B | c.2371dup p.A791Gfs*10 | Frame Shift Ins (INS) | VAF 8/43 reads (19%) | called by mutect2, pindel, varscan2
- RASGRP3 | c.710del p.N237Ifs*5 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- REPS2 | c.1179T>A p.N393K | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- RHBG | c.686T>C p.L229P | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- RNF128 | c.433A>G p.I145V | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- RNF133 | c.416T>G p.V139G | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- RNF146 | c.439G>A p.A147T (on ENST00000368314 / NM_001242850.2; = p.A146T on NM_030963.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- RSRP1 | c.387G>T p.R129S | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RTF1 | c.1504T>C p.F502L | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2, varscan2
- RUVBL1 | c.758del p.G253Dfs*7 | Frame Shift Del (DEL) | VAF 8/30 reads (27%) | called by mutect2, pindel, varscan2
- SALL2 | c.2991del p.R1000Efs*71 | Frame Shift Del (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- SAMD4B | c.530del p.G177Afs*5 | Frame Shift Del (DEL) | VAF 7/20 reads (35%) | called by mutect2, pindel, varscan2
- SBNO2 | c.2834_2835del p.V945Gfs*120 | Frame Shift Del (DEL) | VAF 7/32 reads (22%) | called by pindel, varscan2
- SCAMP2 | c.806C>T p.A269V | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SEC63 | c.1604_1605del p.K535Tfs*24 | Frame Shift Del (DEL) | VAF 23/64 reads (36%) | called by mutect2, varscan2
- SEMA4A | c.1276C>A p.L426I | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.71); PolyPhen benign (0.114); called by muse, mutect2
- SERP2 | c.109G>A p.V37M | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- SETD2 | c.5003T>C p.F1668S | Missense Mutation (SNP) | VAF 80/199 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SHROOM4 | c.136G>A p.A46T | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SIGLEC7 | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- SLC10A4 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, varscan2
- SLC16A1 | c.55G>T p.G19C | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLC1A2 | c.490A>G p.S164G | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by mutect2, varscan2
- SLC22A13 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.085); called by mutect2, varscan2
- SLC25A47 | c.360dup p.V121Sfs*52 | Frame Shift Ins (INS) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.999del p.K333Nfs*20 | Frame Shift Del (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel, varscan2
- SLC29A1 | c.274C>A p.L92M | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); called by muse, mutect2, varscan2
- SLC46A2 | c.940G>A p.G314S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMARCAL1 | c.1621del p.T541Pfs*29 | Frame Shift Del (DEL) | VAF 14/70 reads (20%) | called by pindel, varscan2
- SPATA5 | c.1960A>G p.I654V | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPDYE3 | c.21G>T p.Q7H | Missense Mutation (SNP) | VAF 58/204 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- SPEN | c.4220dup p.L1407Ffs*11 | Frame Shift Ins (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- SPTY2D1 | c.1454del p.P485Rfs*12 | Frame Shift Del (DEL) | VAF 14/47 reads (30%) | called by mutect2, pindel, varscan2
- SRRT | c.335del p.P112Lfs*37 | Frame Shift Del (DEL) | VAF 9/22 reads (41%) | called by mutect2, varscan2
- STAB1 | c.2398del p.V800Cfs*113 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | called by mutect2, pindel, varscan2
- STAT5B | c.1366G>T p.V456F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TANC2 | c.3134dup p.K1046Qfs*39 | Frame Shift Ins (INS) | VAF 4/22 reads (18%) | called by pindel, varscan2
- TDRD6 | c.4289del p.N1430Ifs*5 | Frame Shift Del (DEL) | VAF 8/37 reads (22%) | called by mutect2, pindel, varscan2
- TET1 | c.2392G>A p.A798T | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (0.28); PolyPhen benign (0.005); called by muse, varscan2
- TET3 | c.5243del p.G1748Afs*106 | Frame Shift Del (DEL) | VAF 5/11 reads (45%) | called by mutect2, varscan2
- TGM4 | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.11); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- TGOLN2 | c.1099_1101del p.K367del | In Frame Del (DEL) | VAF 10/32 reads (31%) | called by mutect2, pindel, varscan2
- TIPIN | c.79C>A p.P27T | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); called by muse, mutect2, varscan2
- TKTL2 | c.1115A>G p.N372S | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- TMBIM1 | c.406_409del p.V136Tfs*13 | Frame Shift Del (DEL) | VAF 5/22 reads (23%) | called by mutect2, pindel, varscan2
- TNKS2 | c.1208C>A p.P403H | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNRC6A | c.4456_4457del p.F1486Pfs*2 | Frame Shift Del (DEL) | VAF 13/37 reads (35%) | called by mutect2, pindel, varscan2
- TPO | c.260T>A p.I87N | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- TRIM16L | c.557A>T p.E186V | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- TRIM56 | c.1269del p.A424Pfs*108 | Frame Shift Del (DEL) | VAF 4/37 reads (11%) | called by mutect2, pindel, varscan2
- TRIOBP | c.2950G>A p.G984S | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- TRPM4 | c.3628C>T p.P1210S | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TSHZ2 | c.1251G>T p.K417N | Missense Mutation (SNP) | VAF 11/26 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSNARE1 | c.928G>A p.A310T | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- UHRF1BP1L | c.3902del p.L1301Wfs*9 | Frame Shift Del (DEL) | VAF 18/87 reads (21%) | called by mutect2, pindel, varscan2
- UNC13A | c.1654A>T p.T552S | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- USP13 | c.1762T>A p.F588I | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VHLL | c.83A>G p.E28G | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- VIPR2 | c.991C>T p.L331F | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VXN | c.282G>T p.V94= | Splice Region (SNP) | VAF 18/68 reads (26%) | called by muse, mutect2, varscan2
- WARS1 | c.975del p.R326Gfs*25 | Frame Shift Del (DEL) | VAF 14/49 reads (29%) | called by mutect2, pindel, varscan2
- WDR25 | c.764G>A p.C255Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- XPNPEP1 | c.1613dup p.L538Ffs*5 | Frame Shift Ins (INS) | VAF 6/28 reads (21%) | called by mutect2, pindel, varscan2
- ZKSCAN1 | c.225T>A p.S75R | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- ZNF205 | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0); called by mutect2, varscan2
- ZNF292 | c.3862dup p.S1288Ffs*6 | Frame Shift Ins (INS) | VAF 21/68 reads (31%) | called by mutect2, pindel, varscan2
- ZNF347 | c.1845T>A p.H615Q | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF506 | c.345del p.G116Afs*5 | Frame Shift Del (DEL) | VAF 23/78 reads (29%) | called by mutect2, pindel, varscan2
- ZNF518B | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- ZNF546 | c.1190G>A p.G397D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- ZNF585B | c.2078G>A p.S693N | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF648 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 23/77 reads (30%) | SIFT tolerated (0.11); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- ZNF687 | c.2277_2278del p.R760Pfs*99 | Frame Shift Del (DEL) | VAF 14/58 reads (24%) | called by pindel, varscan2
- ZNF816-ZNF321P | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 28/128 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, varscan2
- AADACL2 | c.405G>A p.T135= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as rs539885775; called by muse, mutect2, varscan2
- ADAMTS13 | c.495C>T p.D165= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs782026673; called by muse, mutect2, varscan2
- ADAMTSL4 | c.2970G>A p.T990= | Silent (SNP) | VAF 18/55 reads (33%) | catalogued as rs368789447, COSV55005111; called by muse, mutect2, varscan2
- AHNAK2 | c.2466C>T p.A822= | Silent (SNP) | VAF 11/58 reads (19%) | catalogued as rs760756862; called by muse, mutect2, varscan2
- ALDH16A1 | c.1998G>T p.V666= | Silent (SNP) | VAF 24/50 reads (48%) | called by muse, mutect2, varscan2
- ALPG | c.1437C>T p.H479= | Silent (SNP) | VAF 6/21 reads (29%) | catalogued as rs770332862; called by muse, mutect2, varscan2
- AMHR2 | c.759G>A p.Q253= | Silent (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2, varscan2
- ANK3 | c.4143G>A p.Q1381= (on ENST00000280772 / NM_001320874.2; = p.Q515= on NM_001149.3) | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as rs769924546, COSV55085739; called by muse, mutect2, varscan2
- ARHGAP4 | c.657G>A p.K219= | Silent (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- ATP11A | c.1329C>T p.N443= | Silent (SNP) | VAF 10/30 reads (33%) | catalogued as rs760113692, COSV52120995; called by muse, mutect2, varscan2
- ATR | c.2922G>A p.T974= | Silent (SNP) | VAF 14/76 reads (18%) | catalogued as rs763559215, COSV63392173; called by muse, mutect2, varscan2
- C15orf40 | c.132A>G p.E44= | Silent (SNP) | VAF 14/50 reads (28%) | called by muse, mutect2, varscan2
- CADM4 | c.444G>A p.P148= | Silent (SNP) | VAF 23/74 reads (31%) | catalogued as COSV55928650, COSV99731421; called by muse, mutect2, varscan2
- CCDC174 | c.1068T>C p.P356= | Silent (SNP) | VAF 9/16 reads (56%) | called by muse, mutect2, varscan2
- CCDC185 | c.1560C>T p.H520= | Silent (SNP) | VAF 11/30 reads (37%) | catalogued as rs749893943, COSV64821666; called by muse, mutect2, varscan2
- CCDC40 | c.2841C>T p.L947= | Silent (SNP) | VAF 14/54 reads (26%) | catalogued as rs573028412; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEP350 | c.8301C>G p.V2767= | Silent (SNP) | VAF 15/94 reads (16%) | called by muse, mutect2, varscan2
- CFAP46 | c.6402C>T p.G2134= | Silent (SNP) | VAF 22/47 reads (47%) | catalogued as rs750033424; called by muse, mutect2, varscan2
- CHD4 | c.1251T>C p.G417= (on ENST00000357008 / NM_001363606.2; = p.G430= on NM_001273.5) | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as rs777924620; called by muse, mutect2, varscan2
- CHD6 | c.7956C>T p.S2652= | Silent (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2, varscan2
- CILP2 | c.1557G>A p.R519= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- COL9A1 | c.1866G>T p.G622= | Silent (SNP) | VAF 11/48 reads (23%) | called by muse, mutect2, varscan2
- CPNE5 | c.1551C>T p.R517= | Silent (SNP) | VAF 15/48 reads (31%) | catalogued as rs140027543, COSV55197525; called by muse, mutect2, varscan2
- CPNE7 | c.1104G>A p.V368= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs1305394919, COSV52012141; called by muse, mutect2, varscan2
- CROCC | c.3693C>T p.S1231= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs572221552, COSV65009950; called by muse, varscan2
- CYBC1 | c.534T>C p.S178= | Silent (SNP) | VAF 6/35 reads (17%) | called by muse, mutect2, varscan2
- CYP26A1 | c.96C>T p.C32= | Silent (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
- DCAF12 | c.1047C>T p.Y349= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as rs749579942; called by muse, mutect2, varscan2
- DYSF | c.3606G>A p.T1202= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs139897804; called by muse, mutect2, varscan2
- EGFLAM | c.498G>A p.A166= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs758620907; called by mutect2, varscan2
- EVX2 | c.504C>T p.G168= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- FAM183A | c.312C>T p.R104= | Silent (SNP) | VAF 6/28 reads (21%) | called by muse, mutect2, varscan2
- FOXD4 | c.216C>T p.G72= | Silent (SNP) | VAF 20/91 reads (22%) | called by muse, varscan2
- FOXK1 | c.1602G>A p.S534= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1270330899; called by muse, mutect2, varscan2
- FRMPD2 | c.1011C>A p.S337= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as COSV100563543; called by muse, mutect2, varscan2
- FST | c.912A>G p.S304= | Silent (SNP) | VAF 8/34 reads (24%) | called by muse, mutect2, varscan2
- GABRR1 | c.1011C>T p.R337= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as rs185458142, COSV65619626, COSV65620358; called by mutect2, varscan2
- GLI3 | c.3867C>T p.S1289= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV67891494; called by muse, mutect2, varscan2
- GNAZ | c.96C>T p.R32= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as rs780522450; called by muse, mutect2, varscan2
- HARS2 | c.501C>T p.G167= | Silent (SNP) | VAF 20/74 reads (27%) | catalogued as rs907739397; called by muse, mutect2, varscan2
- IGHE | c.1104C>T p.D368= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs782704173; called by muse, mutect2, varscan2
- IGHJ6 | c.51C>T p.T17= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as rs372706912; called by muse, mutect2, varscan2
- IGKV2D-24 | c.75C>A p.T25= | Silent (SNP) | VAF 21/72 reads (29%) | called by muse, mutect2, varscan2
- INHBC | c.75G>A p.Q25= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- IRS2 | c.3528C>T p.S1176= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as rs1012728779; called by muse, mutect2, varscan2
- JAML | c.528C>T p.R176= (on ENST00000356289 / NM_001098526.2; = p.R166= on NM_153206.3) | Silent (SNP) | VAF 14/48 reads (29%) | catalogued as rs762252806, COSV99409757; called by muse, mutect2, varscan2
- KCNC1 | c.249C>T p.C83= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV56391450; called by muse, mutect2, varscan2
- KIAA0100 | c.2907A>G p.A969= | Silent (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- KMT5B | c.1923G>A p.A641= | Silent (SNP) | VAF 4/15 reads (27%) | catalogued as rs773565168; called by muse, varscan2
- LAMA5 | c.1317C>T p.T439= | Silent (SNP) | VAF 11/38 reads (29%) | called by muse, mutect2, varscan2
- LPO | c.123C>T p.A41= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99229537; called by muse, mutect2, varscan2
- LRRC8E | c.1635C>T p.N545= | Silent (SNP) | VAF 9/30 reads (30%) | catalogued as rs139771650; called by muse, mutect2, varscan2
- LRRN2 | c.930C>T p.P310= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs754106618; called by muse, mutect2, varscan2
- MAGEB10 | c.591C>T p.G197= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs374712101, COSV63310989; called by muse, mutect2, varscan2
- MAP3K21 | c.1419C>T p.D473= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as rs759303296; called by muse, mutect2, varscan2
- MAP3K5 | c.2391T>C p.N797= | Silent (SNP) | VAF 23/96 reads (24%) | called by muse, mutect2, varscan2
- MGAT2 | c.630C>T p.C210= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs1449092316; called by muse, mutect2, varscan2
- MOB3A | c.282C>G p.G94= | Silent (SNP) | VAF 21/63 reads (33%) | called by muse, mutect2, varscan2
- MRC2 | c.657C>T p.Y219= | Silent (SNP) | VAF 11/29 reads (38%) | catalogued as rs564657391, COSV57640517; called by muse, mutect2, varscan2
- MRPL3 | c.1026G>A p.A342= | Silent (SNP) | VAF 6/49 reads (12%) | catalogued as rs772132219; called by muse, mutect2, varscan2
- MTCH1 | c.1134C>T p.R378= (on ENST00000373627 / NM_001271641.1; = p.R361= on NM_014341.2) | Silent (SNP) | VAF 5/25 reads (20%) | catalogued as rs147639756; called by muse, mutect2
- MYADM | c.12G>A p.T4= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as rs1255588157; called by muse, mutect2
- MYH14 | c.207G>A p.A69= | Silent (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2
- NBEA | c.2478A>G p.V826= | Silent (SNP) | VAF 12/38 reads (32%) | catalogued as COSV100078871; called by muse, mutect2, varscan2
- NETO2 | c.1290C>T p.T430= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs746323210; called by muse, mutect2, varscan2
- NKD1 | c.123G>A p.Q41= | Silent (SNP) | VAF 21/55 reads (38%) | called by muse, mutect2, varscan2
- NLK | c.321A>T p.A107= | Silent (SNP) | VAF 37/113 reads (33%) | called by muse, mutect2, varscan2
- NLRP12 | c.2274C>A p.A758= | Silent (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- NRG1 | c.1341G>A p.S447= (on ENST00000405005 / NM_013964.5; = p.S452= on NM_013956.5) | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as rs1207291374; called by muse, mutect2, varscan2
- OBSCN | c.18399C>T p.G6133= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as rs1030913682, COSV52765913; called by muse, mutect2, varscan2
- OR6C1 | c.753C>T p.G251= | Silent (SNP) | VAF 15/53 reads (28%) | called by muse, mutect2, varscan2
- PARP6 | c.957C>T p.G319= | Silent (SNP) | VAF 6/20 reads (30%) | catalogued as rs370713698; called by muse, mutect2, varscan2
- PCDHA12 | c.1887C>T p.G629= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV56482481; called by muse, mutect2, varscan2
- PCDHA5 | c.144G>A p.A48= | Silent (SNP) | VAF 14/50 reads (28%) | catalogued as rs190099815; called by muse, varscan2
- PCDHA7 | c.1449C>T p.D483= | Silent (SNP) | VAF 20/82 reads (24%) | catalogued as COSV100971195; called by muse, mutect2, varscan2
- PCDHGA8 | c.1989C>T p.A663= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs773531449, COSV99548883; called by muse, mutect2, varscan2
- PDE4DIP | c.4830C>A p.T1610= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV57731872; called by muse, varscan2
- PGD | c.1041C>T p.T347= | Silent (SNP) | VAF 12/29 reads (41%) | catalogued as rs530138934; called by muse, mutect2, varscan2
- PHGDH | c.180C>T p.T60= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs769991971; ClinVar: likely benign; called by muse, mutect2, varscan2
- POLH | c.939G>A p.R313= | Silent (SNP) | VAF 23/84 reads (27%) | called by muse, mutect2, varscan2
- PRG4 | c.1215A>G p.A405= | Silent (SNP) | VAF 23/119 reads (19%) | called by muse, mutect2, varscan2
- PRKDC | c.3702C>T p.G1234= | Silent (SNP) | VAF 15/52 reads (29%) | catalogued as rs1338750857; called by muse, mutect2, varscan2
- PRMT5 | c.555G>A p.T185= | Silent (SNP) | VAF 11/38 reads (29%) | catalogued as rs759956527; called by muse, mutect2, varscan2
- PSME4 | c.735G>A p.V245= | Silent (SNP) | VAF 77/253 reads (30%) | catalogued as rs767442741; called by muse, mutect2, varscan2
- RBM8A | c.429C>A p.P143= | Silent (SNP) | VAF 14/82 reads (17%) | called by muse, mutect2, varscan2
- RGR | c.726C>T p.D242= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs772574741; called by muse, mutect2, varscan2
- RGS3 | c.987G>A p.P329= (on ENST00000350696 / NM_001282923.2; = p.P217= on NM_017790.4) | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs565492325; called by muse, mutect2, varscan2
- RHBDD2 | c.279C>T p.T93= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs372131603; called by muse, mutect2, varscan2
- RIN1 | c.18G>A p.E6= | Silent (SNP) | VAF 12/40 reads (30%) | called by muse, mutect2, varscan2
- RNF213 | c.195G>A p.P65= | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs370520790; called by muse, mutect2
- SCN3A | c.5223T>C p.C1741= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- SCNN1A | c.822G>A p.T274= | Silent (SNP) | VAF 13/31 reads (42%) | catalogued as rs372634287; called by muse, mutect2, varscan2
- SETDB2 | c.1245C>T p.N415= | Silent (SNP) | VAF 9/57 reads (16%) | catalogued as rs756483305, COSV51647198; called by muse, mutect2, varscan2
- SHANK3 | c.3618C>T p.H1206= | Silent (SNP) | VAF 4/21 reads (19%) | catalogued as rs764950597, COSV99436368; called by muse, mutect2
- SIAE | c.999C>T p.D333= | Silent (SNP) | VAF 25/49 reads (51%) | catalogued as rs371229601; called by muse, mutect2, varscan2
- SLC35D2 | c.333C>T p.S111= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs748309846; called by muse, mutect2, varscan2
- SLC4A5 | c.1908C>T p.T636= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs759680827, COSV61030271; called by muse, mutect2, varscan2
- SLC4A5 | c.366T>C p.H122= | Silent (SNP) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- SLIT2 | c.2883C>T p.C961= | Silent (SNP) | VAF 7/33 reads (21%) | called by muse, mutect2, varscan2
- SLITRK3 | c.1398C>T p.N466= | Silent (SNP) | VAF 23/75 reads (31%) | catalogued as rs140074591, COSV53852101, COSV99579390; called by muse, mutect2, varscan2
- SMG7 | c.1632G>T p.V544= | Silent (SNP) | VAF 11/44 reads (25%) | called by muse, mutect2, varscan2
- SNAPC4 | c.468C>T p.G156= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs766890455, COSV53734785; called by muse, mutect2, varscan2
- SP3 | c.1572T>C p.V524= | Silent (SNP) | VAF 12/52 reads (23%) | called by muse, mutect2, varscan2
- SPICE1 | c.1062C>T p.R354= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as rs758379923; called by mutect2, varscan2
- SSTR4 | c.297C>T p.S99= | Silent (SNP) | VAF 5/11 reads (45%) | catalogued as COSV54797126; called by muse, mutect2, varscan2
- STAG1 | c.759C>T p.A253= | Silent (SNP) | VAF 17/74 reads (23%) | catalogued as rs113504457; called by muse, mutect2, varscan2
- SYNPO2 | c.852G>A p.V284= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- TACC2 | c.726G>A p.G242= | Silent (SNP) | VAF 10/32 reads (31%) | called by muse, mutect2, varscan2
- TAS1R1 | c.618C>T p.F206= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs755344013, COSV60227564; called by muse, mutect2, varscan2
- TBXA2R | c.987G>A p.S329= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs1467682445; called by muse, mutect2, varscan2
- TCHP | c.1431G>A p.A477= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs368260508; called by muse, mutect2, varscan2
- TENM2 | c.2145G>A p.T715= (on ENST00000518659 / NM_001122679.2; = p.T483= on NM_001080428.3) | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as rs1333891430, COSV69140727; called by muse, mutect2, varscan2
- TENM4 | c.6750C>T p.D2250= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs753999795, COSV53626872; called by muse, mutect2
- TET1 | c.4161A>G p.T1387= | Silent (SNP) | VAF 16/83 reads (19%) | called by muse, mutect2, varscan2
- TGM1 | c.537G>A p.T179= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs757301708, COSV52862233; called by muse, mutect2, varscan2
- TLR3 | c.610T>C p.L204= | Silent (SNP) | VAF 31/100 reads (31%) | called by muse, mutect2, varscan2
- TMCC2 | c.1125C>T p.D375= | Silent (SNP) | VAF 8/38 reads (21%) | catalogued as rs769770108; called by muse, varscan2
- TP53BP1 | c.4063C>A p.R1355= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV55510993; called by muse, mutect2, varscan2
- TPR | c.3303G>A p.E1101= | Silent (SNP) | VAF 12/58 reads (21%) | called by muse, mutect2, varscan2
- TPSG1 | c.189C>T p.C63= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as rs376013233; called by muse, mutect2
- TRPC7 | c.1446C>T p.F482= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as rs368396777, COSV61452079; called by muse, mutect2, varscan2
- TTI1 | c.2925G>A p.S975= | Silent (SNP) | VAF 5/28 reads (18%) | catalogued as rs760307030; called by muse, mutect2, varscan2
- UBE2S | c.609C>T p.R203= | Silent (SNP) | VAF 27/106 reads (25%) | catalogued as rs1320986420, COSV99198768; called by muse, mutect2, varscan2
- UCP1 | c.402A>G p.T134= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- USP38 | c.193C>T p.L65= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV61025735; called by muse, mutect2, varscan2
- USP51 | c.528T>A p.P176= | Silent (SNP) | VAF 4/58 reads (7%) | called by muse, mutect2
- VPS13C | c.1065G>A p.A355= (on ENST00000644861 / NM_020821.3; = p.A312= on NM_017684.5) | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs767109326, COSV51121152; called by muse, mutect2, varscan2
- VWF | c.3366G>A p.T1122= | Silent (SNP) | VAF 25/91 reads (27%) | catalogued as rs373172467; called by muse, mutect2, varscan2
- WNK2 | c.5376C>T p.D1792= (on ENST00000297954 / NM_001282394.1; = p.D1755= on NM_006648.3) | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs1024682818; called by mutect2, varscan2
- WSCD1 | c.55C>T p.L19= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- WWC3 | c.624C>T p.C208= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs757435646; called by muse, mutect2, varscan2
- WWC3 | c.2793G>A p.T931= | Silent (SNP) | VAF 21/70 reads (30%) | called by muse, mutect2, varscan2
- ZBTB45 | c.183G>A p.K61= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV63524394; called by muse, mutect2, varscan2
- ZFHX4 | c.9777C>T p.G3259= | Silent (SNP) | VAF 5/26 reads (19%) | catalogued as rs778232576, COSV50533655, COSV99264932; called by muse, mutect2, varscan2
- ZNF286A | c.399A>G p.S133= | Silent (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- ZNF587 | c.1434C>T p.S478= | Silent (SNP) | VAF 17/60 reads (28%) | catalogued as rs769831329, COSV100299695; called by muse, mutect2, varscan2
- ZNF629 | c.2001C>T p.C667= | Silent (SNP) | VAF 10/36 reads (28%) | called by muse, mutect2, varscan2
- ZNF808 | c.2256C>T p.C752= | Silent (SNP) | VAF 19/81 reads (23%) | catalogued as COSV63119046; called by muse, mutect2, varscan2
- ZNF835 | c.1272C>T p.G424= | Silent (SNP) | VAF 6/19 reads (32%) | called by muse, mutect2, varscan2
- ZP4 | c.69T>C p.P23= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as COSV63913288; called by muse, mutect2, varscan2
- AK9 | c.3633+23del | Intron (DEL) | VAF 22/63 reads (35%) | catalogued as rs552385212; called by mutect2, varscan2
- AL353804.6 | chrX:73827301 G>A | 3'Flank (SNP) | VAF 16/28 reads (57%) | catalogued as rs1316848170; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501842 G>A | 5'Flank (SNP) | VAF 18/61 reads (30%) | catalogued as rs960180578; called by muse, mutect2, varscan2
- AP2A2 | c.*482C>A | 3'UTR (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
- CCNQP1 | n.441dup | RNA (INS) | VAF 8/58 reads (14%) | catalogued as rs755722106; called by mutect2, pindel, varscan2
- DDX39B | c.-2-611C>T | Intron (SNP) | VAF 13/43 reads (30%) | called by muse, mutect2, varscan2
- DLG2 | c.205-21861C>T | Intron (SNP) | VAF 26/92 reads (28%) | catalogued as rs780023036; called by muse, mutect2, varscan2
- DNAH8 | c.-226G>A | 5'UTR (SNP) | VAF 15/30 reads (50%) | catalogued as rs1221155183, COSV59474262; called by muse, mutect2, varscan2
- EEF1D | c.-7-2247G>A | Intron (SNP) | VAF 11/32 reads (34%) | catalogued as rs945908580; called by muse, mutect2, varscan2
- FGFR3 | c.*808G>A | 3'UTR (SNP) | VAF 10/46 reads (22%) | catalogued as rs139020690; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- MIR1257 | n.67G>A | RNA (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- MIR181B1 | n.61A>T | RNA (SNP) | VAF 13/53 reads (25%) | called by muse, mutect2, varscan2
- NXT2 | c.*2G>T | 3'UTR (SNP) | VAF 33/142 reads (23%) | called by muse, mutect2, varscan2
- PCID2 | c.266+140G>A | Intron (SNP) | VAF 18/62 reads (29%) | catalogued as rs368517651; called by muse, mutect2, varscan2
- PRKACB | c.47-91del | Intron (DEL) | VAF 51/177 reads (29%) | catalogued as rs1362035564; called by mutect2, pindel, varscan2
- REXO1L1P | n.1410C>T | RNA (SNP) | VAF 15/275 reads (5%) | called by muse, mutect2
- SREBF1 | c.92-3018G>T | Intron (SNP) | VAF 24/87 reads (28%) | called by muse, mutect2, varscan2
- TRAV36DV7 | chr14:22222279 G>A | 5'Flank (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2
- ZNF419 | c.298+25A>G | Intron (SNP) | VAF 24/69 reads (35%) | called by muse, mutect2, varscan2
